Somatic mutation profile of tumor specimen TCGA-HT-A74K-01A (aliquot TCGA-HT-A74K-01A-11D-A32B-08) from TCGA case TCGA-HT-A74K, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 58.0 years (21,189 days).
Specimen TCGA-HT-A74K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cdf0b78-84e9-461e-b009-02769b776145.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A74K-10A (Blood Derived Normal), aliquot TCGA-HT-A74K-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6130e9ab-675c-4304-be63-850b20fb0874

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 20, Silent 9, Frame Shift Ins 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- BRCA2 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as rs138734772, CM057322, COSV101204503; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRD3 | c.1754A>G p.N585S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV100325351; called by muse, mutect2, varscan2
- CLIP1 | c.2963A>G p.Q988R (on ENST00000620786 / NM_001247997.1; = p.Q977R on NM_002956.2) | Missense Mutation (SNP) | VAF 106/252 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV100212115; called by muse, varscan2
- DNAJB7 | c.884dup p.K296Efs*3 | Frame Shift Ins (INS) | VAF 24/88 reads (27%) | catalogued as rs768619916; called by mutect2, varscan2
- DPP4 | c.1012A>G p.N338D | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100858967; called by muse, mutect2, varscan2
- DYSF | c.4457G>A p.G1486E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99249165; called by muse, mutect2, varscan2
- ECT2L | c.1341C>G p.I447M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.157); catalogued as COSV100872087; called by muse, mutect2, varscan2
- GRWD1 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs201501296, COSV99474488; called by muse, mutect2, varscan2
- HNF1B | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM145219; called by muse, mutect2, varscan2
- MSGN1 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.232); catalogued as COSV99808796; called by muse, mutect2, varscan2
- NDUFB5 | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251625332, COSV99372616; called by muse, mutect2, varscan2
- NPC1L1 | c.1849G>A p.A617T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV99212842; called by muse, mutect2
- NPR3 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.14); catalogued as rs374966067; called by muse, mutect2, varscan2
- OBSCN | c.15592C>T p.R5198C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373582245, COSV99482361; called by muse, varscan2
- OR10R2 | c.790C>T p.H264Y | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV100936814; called by muse, mutect2, varscan2
- OR8H3 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV57909034, COSV57910739; called by muse, mutect2, varscan2
- RASAL2 | c.2794A>G p.K932E | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.843); catalogued as COSV100862735; called by muse, mutect2, varscan2
- VGLL2 | c.920G>A p.R307H (on ENST00000326274 / NM_182645.3; = p.R133H on NM_153453.1) | Missense Mutation (SNP) | VAF 114/350 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100409963; called by muse, mutect2, varscan2
- ZNF91 | c.1633C>G p.P545A | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV100323215; called by muse, mutect2, varscan2
- HMGXB4 | c.102dup p.R35Tfs*28 | Frame Shift Ins (INS) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- NPTXR | c.873_877dup p.A293Efs*62 | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1145_1147del p.K382del (on ENST00000521381 / NM_181523.3; = p.K112del on NM_181504.4) | In Frame Del (DEL) | VAF 31/103 reads (30%) | called by mutect2, pindel, varscan2
- TPTE | c.576T>A p.H192Q (on ENST00000618007 / NM_199261.4; = p.H174Q on NM_199259.4) | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- ACSS3 | c.333C>T p.N111= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs548439952, COSV54098151; called by muse, mutect2, varscan2
- CUBN | c.8574A>G p.G2858= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as COSV100913138; called by muse, mutect2, varscan2
- DISP1 | c.3990G>A p.T1330= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs370266646, COSV99451432; called by muse, mutect2, varscan2
- DNAJC6 | c.2115G>A p.P705= | Silent (SNP) | VAF 22/30 reads (73%) | catalogued as rs367640667; called by muse, mutect2, varscan2
- HUS1B | c.462C>T p.D154= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as rs753972185, COSV100033954; called by muse, mutect2, varscan2
- KANSL1L | c.51T>C p.S17= | Silent (SNP) | VAF 6/105 reads (6%) | catalogued as COSV99910777; called by muse, mutect2
- KAT6A | c.2718A>G p.S906= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs368865750; called by muse, mutect2, varscan2
- OR2T3 | c.726C>T p.A242= | Silent (SNP) | VAF 88/214 reads (41%) | catalogued as COSV100613312; called by muse, mutect2, varscan2
- OR5AC2 | c.615T>A p.G205= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV100684437; called by muse, mutect2, varscan2
